Gene-level copy-number profile of tumor specimen TCGA-23-1123-01A from TCGA case TCGA-23-1123, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 59.0 years (21,552 days).
Specimen TCGA-23-1123-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.68b7f950-ef65-40a8-8ead-3c28e800c770.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1123-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bb1360d6-fbfc-4fe2-90f1-a3ab71dfecc5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,770; copy number 2: 24,110; copy number 3: 19,440; copy number 4: 9,799; copy number 5: 1,995; copy number 6: 1,135; copy number 7: 829; copy number 8: 141; copy number 9: 230; copy number 10: 21; copy number 11: 86; copy number 12: 44; copy number 13: 20; copy number 14: 81; copy number 16: 25; copy number 17: 59; copy number 21: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1123-01A-01D-0428-01): tumor purity 0.8, ploidy 2.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,498 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,042,184–237,833,988, 1 gene, copy number 5 (within-gene range 4–5): RYR2.
- chr1:237,471,119–241,357,230, 54 genes, copy number 5 (within-gene range 4–5): MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123.
- chr2:55,865,967–56,386,172, 12 genes, copy number 6: EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813, AC007744.1, AC007743.1, CCDC85A, RNA5SP93.
- chr2:61,177,418–62,491,468, 32 genes, copy number 5: AHSA2P, USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3, AC016727.2, RPS29P10, RNU6-1145P, AC108039.1, RPS24P7, AC108039.2, FAM161A, RPL31P30, AC107081.2, CCT4, AC107081.1, AC107081.3, COMMD1, Y_RNA, AC018462.1, RPSAP26, AC018462.2, B3GNT2, MIR5192, RN7SL51P, AC093159.2, AC093159.1, RN7SL18P.
- chr2:110,083,870–110,116,022, 1 gene, copy number 5 (within-gene range 4–5): MALL.
- chr2:110,122,311–113,278,921, 96 genes, copy number 5 (broad region; genes not listed).
- chr2:150,468,195–151,380,046, 15 genes, copy number 7: RND3, LINC01920, AC104777.2, AC104777.1, LINC02612, AC023469.2, AC023469.1, AC018731.1, FABP5P10, RBM43, NMI, TNFAIP6, MIR4773-1, MIR4773-2, RN7SL124P.
- chr2:152,176,020–162,371,595, 140 genes, copy number 5–7 (broad region; genes not listed).
- chr2:162,496,936–162,497,051, 1 gene, copy number 7: RNA5SP109.
- chr2:179,101,678–180,007,297, 9 genes, copy number 5: SESTD1, AC093911.1, RAD52P1, ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22.
- chr2:201,063,089–201,229,406, 17 genes, copy number 14: HNRNPA1P35, RPL23AP30, NDUFB3, RNU6-1206P, Metazoa_SRP, AC007272.1, RPL17P10, CFLAR, IMPDH1P10, CFLAR-AS1, RNU7-45P, RPL38P5, AC007283.1, CASP10, MTND5P25, MTND4P23, MTND4LP13.
- chr2:211,535,653–211,535,769, 1 gene, copy number 14: RNA5SP119.
- chr4:44,016,700–44,678,556, 4 genes, copy number 5 (within-gene range 2–5): LINC02475, KCTD8, AC093852.1, YIPF7.
- chr4:71,741,696–75,195,079, 56 genes, copy number 8–21: GC, RNA5SP163, AC068721.1, NPFFR2, ADAMTS3, AC095056.1, HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1, PF4, PPBP, CXCL5, AC097709.1, RN7SL218P, CXCL3, PPBPP2, AC093677.3, AC093677.1, CXCL2, MTHFD2L, AC093677.2, EPGN, EREG, AC021180.1, AREG, AC239584.1, BTC, AC098825.1, HSPE1P23, PARM1, PARM1-AS1, AC110760.1, LINC02562, AC110760.2, AC093870.1.
- chr4:148,078,762–148,444,698, 1 gene, copy number 11 (within-gene range 2–11): NR3C2.
- chr7:63,011,463–70,793,506, 220 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:71,132,144–71,713,600, 1 gene, copy number 6 (within-gene range 3–6): GALNT17.
- chr7:71,685,452–71,685,747, 1 gene, copy number 6: RN7SKP75.
- chr8:6,036,433–19,758,029, 376 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:33,969,567–34,009,595, 2 genes, copy number 5: AF279873.1, AF279873.4.
- chr8:35,862,123–42,271,266, 140 genes, copy number 6 (broad region; genes not listed).
- chr9:12,685,439–13,034,326, 8 genes, copy number 6: TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1.
- chr9:13,738,537–15,307,360, 26 genes, copy number 6–9: AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B.
- chr9:33,290,512–34,774,466, 80 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr13:105,410,816–107,933,503, 33 genes, copy number 5: AL138954.1, DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1, LINC00343, AL138701.1, AL138701.2, RNA5SP38, AL139379.1, LINC00460, RPL35P9, EFNB2, AL138689.2, AL138689.1, ARGLU1, LINC00551, LINC00443, ATP5MC1P5, AL163534.1, AL162574.2, PPIAP24, AL162574.1, AL162574.3, AL354741.1, FAM155A, SNORD31B, AL445649.1, MIR1267, FAM155A-IT1, AL359436.1, AL136964.1.
- chr13:112,894,378–113,099,742, 1 gene, copy number 5 (within-gene range 4–5): MCF2L.
- chr13:113,008,778–113,554,590, 24 genes, copy number 5: AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1.
- chr14:18,333,726–31,488,039, 556 genes, copy number 7–14 (broad region; genes not listed).
- chr14:31,553,358–31,561,334, 2 genes, copy number 14: AL163973.3, AL163973.2.
- chr18:47,390–36,279,119, 629 genes, copy number 5–14 (broad region; genes not listed).
- chr18:36,417,055–36,424,185, 1 gene, copy number 14: AC055840.1.
- chr19:10,598,001–30,228,715, 787 genes, copy number 5–12 (broad region; genes not listed).
- chr20:87,250–13,169,103, 271 genes, copy number 8–17 (broad region; genes not listed).
- chr20:13,237,801–13,239,674, 1 gene, copy number 17: ISM1-AS1.
- chr20:30,214,765–64,313,132, 899 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,770. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
